Somatic mutation profile of tumor specimen 0DP4Q8 from CCDI case PBCDFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,628 days).
Specimen 0DP4Q8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50885db6-d3e7-4b3c-8587-a4ea119a4366.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4P5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81a037d0-c3fb-40af-b452-6f092399a331

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB11FIP1 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs149715270; called by muse, varscan2
- TAS1R2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 150/346 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as rs779107865, COSV64747170; called by muse, varscan2
- ZKSCAN8 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 142/300 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PCDHB4 | c.204C>T p.D68= | Silent (SNP) | VAF 119/278 reads (43%) | catalogued as rs377174176; called by muse, varscan2
- UTS2R | c.87C>T p.N29= | Silent (SNP) | VAF 90/224 reads (40%) | catalogued as rs536506503; called by muse, varscan2
